Somatic mutation profile of tumor specimen TCGA-Y8-A8RY-01A (aliquot TCGA-Y8-A8RY-01A-11D-A36X-10) from TCGA case TCGA-Y8-A8RY, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.5 years (23,192 days).
Specimen TCGA-Y8-A8RY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 212424e2-2da0-413a-a8cf-d56279df1b5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A8RY-10A (Blood Derived Normal), aliquot TCGA-Y8-A8RY-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f73548a-b2e8-4520-9abb-f8b6a2f33312

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 18, Frame Shift Del 8, Nonsense Mutation 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD16 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as rs774806484, COSV51947720, COSV99510373; called by muse, mutect2, varscan2
- APH1A | c.575T>A p.L192Q | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); catalogued as COSV99354255; called by muse, mutect2, varscan2
- CBFA2T2 | c.412G>C p.G138R | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100656143; called by muse, mutect2, varscan2
- CHD1 | c.1037T>A p.M346K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV99399103; called by muse, mutect2, varscan2
- COL25A1 | c.583G>C p.G195R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101211206; called by muse, mutect2, varscan2
- COL4A2 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV64627428; called by muse, mutect2, varscan2
- CTDSP1 | c.541T>A p.C181S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99811871; called by muse, mutect2, varscan2
- DEFB116 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV101269204; called by muse, mutect2, varscan2
- DEFB116 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV101269206; called by muse, mutect2, varscan2
- ENOX2 | c.325T>C p.F109L (on ENST00000338144 / NM_001382520.1; = p.F80L on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100583785; called by muse, mutect2, varscan2
- FBN1 | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CS102148, COSV100354052; called by muse, mutect2, varscan2
- FCHSD2 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as COSV100237899; called by muse, mutect2, varscan2
- FGFR4 | c.1892T>C p.F631S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99448859; called by muse, mutect2, varscan2
- GFPT2 | c.1255T>C p.F419L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as COSV99517298; called by muse, mutect2, varscan2
- GPSM1 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100696551; called by muse, mutect2, varscan2
- HDAC7 | c.2288G>C p.G763A (on ENST00000427332; = p.G802A on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99315584; called by muse, mutect2, varscan2
- KNDC1 | c.2269G>A p.G757S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.086); catalogued as COSV100463387; called by muse, mutect2, varscan2
- M1AP | c.1020G>A p.W340* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as COSV51849224, COSV99303697; called by muse, mutect2, varscan2
- MAST2 | c.5127T>A p.S1709R | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV99421381; called by muse, mutect2, varscan2
- MYH1 | c.3272T>A p.M1091K | Missense Mutation (SNP) | VAF 75/123 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99874953; called by muse, mutect2, varscan2
- NAA16 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101038239; called by muse, mutect2, varscan2
- NBEAL2 | c.2747C>T p.T916M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as rs764272685, COSV52763871; called by muse, mutect2, varscan2
- NOXRED1 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV53629249; called by muse, mutect2, varscan2
- POU2F1 | c.511C>T p.Q171* (on ENST00000541643 / NM_001365848.1; = p.Q194* on NM_002697.4) | Nonsense Mutation (SNP) | VAF 74/183 reads (40%) | catalogued as COSV99610470; called by muse, mutect2, varscan2
- QSOX1 | c.598G>C p.G200R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852810; called by muse, mutect2, varscan2
- RIMKLA | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV101290551; called by muse, mutect2, varscan2
- RPL36A | c.271T>G p.F91V | Missense Mutation (SNP) | VAF 83/109 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99516174; called by muse, mutect2, varscan2
- RSF1 | c.2066C>A p.S689Y | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100406903; called by muse, mutect2, varscan2
- SHROOM1 | c.918C>A p.S306R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1196557659, COSV100166952; called by muse, mutect2, varscan2
- SLC25A40 | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 186/305 reads (61%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100353575; called by muse, mutect2, varscan2
- SLC4A1 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs373768879, CM983769, COSV99293058; called by muse, mutect2, varscan2
- STING1 | c.957T>G p.D319E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100423422; called by muse, mutect2, varscan2
- TEKT2 | c.968A>T p.Y323F | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.697); catalogued as COSV99255386; called by muse, mutect2, varscan2
- TENM3 | c.3925G>A p.D1309N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as rs756039891, COSV101304894; called by muse, mutect2, varscan2
- TMEM79 | c.1065G>C p.W355C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV99827751; called by muse, mutect2, varscan2
- TREH | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV99874190; called by muse, mutect2, varscan2
- ZSCAN21 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 106/165 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV99460653; called by muse, mutect2, varscan2
- ABCA12 | c.6252_6253del p.W2084Cfs*10 (on ENST00000272895 / NM_173076.3; = p.W1766Cfs*10 on NM_015657.3) | Frame Shift Del (DEL) | VAF 85/267 reads (32%) | called by mutect2, pindel, varscan2
- ACOT11 | c.562del p.A188Qfs*77 | Frame Shift Del (DEL) | VAF 52/173 reads (30%) | called by mutect2, pindel, varscan2
- ADAD1 | c.1099del p.Y367Ifs*2 | Frame Shift Del (DEL) | VAF 36/95 reads (38%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.2514_2520del p.N838Kfs*105 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- MYL12B | c.65del p.V22Gfs*19 | Frame Shift Del (DEL) | VAF 53/170 reads (31%) | called by mutect2, pindel, varscan2
- NCOA2 | c.1946del p.S649Lfs*9 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- PGM1 | c.1626del p.I542Mfs*3 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- TTYH3 | c.297del p.G100Afs*44 | Frame Shift Del (DEL) | VAF 31/68 reads (46%) | called by mutect2, pindel, varscan2
- ACVR2A | c.1008T>A p.A336= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV99603934; called by muse, mutect2, varscan2
- ADTRP | c.312C>T p.I104= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV99995042; called by muse, mutect2, varscan2
- AMER1 | c.2103G>C p.L701= | Silent (SNP) | VAF 47/57 reads (82%) | catalogued as COSV100365343; called by muse, mutect2, varscan2
- BEND3 | c.1650T>C p.G550= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100944544; called by muse, mutect2, varscan2
- BRAF | c.660A>G p.E220= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV99951740; called by muse, mutect2, varscan2
- CEP152 | c.4275C>T p.N1425= (on ENST00000380950 / NM_001194998.2; = p.N1369= on NM_014985.4) | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV100358507; called by muse, mutect2, varscan2
- DAGLA | c.333C>T p.Y111= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs374808753; called by muse, mutect2, varscan2
- DLAT | c.1827T>A p.A609= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99734424; called by muse, mutect2, varscan2
- DNAH11 | c.13500G>A p.E4500= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as COSV100177257; called by muse, mutect2, varscan2
- DUSP4 | c.490C>T p.L164= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99529593; called by muse, mutect2, varscan2
- GTF2H1 | c.1485T>C p.S495= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99786301; called by muse, mutect2, varscan2
- INPPL1 | c.1188C>A p.V396= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV99995852; called by muse, mutect2, varscan2
- KIF21A | c.4830C>G p.V1610= (on ENST00000361418 / NM_001378440.1; = p.V1597= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 119/232 reads (51%) | catalogued as rs576774677, COSV100735294; called by muse, mutect2, varscan2
- NBR1 | c.594T>C p.P198= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV100357690; called by muse, mutect2, varscan2
- TMPRSS13 | c.357G>A p.V119= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV101471367; called by muse, mutect2, varscan2
- TTC9 | c.282C>T p.P94= | Silent (SNP) | VAF 80/176 reads (45%) | catalogued as rs781750643, COSV56448279, COSV99832775; called by muse, mutect2
- VPS13B | c.9327T>C p.T3109= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100660894; called by muse, mutect2, varscan2
- ZNF689 | c.561C>A p.S187= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99787857; called by muse, mutect2, varscan2
- OR2U1P | n.107C>G | RNA (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
